Somatic mutation profile of tumor specimen MMRF_1738_1_BM_CD138pos (aliquot MMRF_1738_1_BM_CD138pos_T1_KBS5U_L07227) from MMRF case MMRF_1738, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 78.3 years (28,595 days).
Specimen MMRF_1738_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cdb84b8-4779-41f8-a78a-609d9fd6501a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1738_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1738_1_PB_WBC_C3_KBS5U_L07228; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a209664c-f44e-4b2e-88a1-dbade196b9b6

The open-access MAF lists 232 somatic variants for this specimen: 98 protein-altering or splice-affecting, 24 silent, 110 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, 3'UTR 54, Intron 32, Silent 24, 5'UTR 11, Nonsense Mutation 8, 3'Flank 5, 5'Flank 5, Splice Site 3, RNA 3, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3568G>A p.A1190T | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs779472538, COSV99079573; called by muse, mutect2, varscan2
- ADCY6 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs776649456; called by muse, mutect2, varscan2
- AKR1B15 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs374929844; called by muse, mutect2, varscan2
- ATP8B4 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs755515439, COSV52709807; called by muse, mutect2, varscan2
- BRCA2 | c.3152T>C p.L1051S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.388); catalogued as rs778281493; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK13 | c.485C>G p.A162G | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.026); catalogued as rs1216683440, COSV51697392; called by muse, mutect2, varscan2
- CRYBG2 | c.4714G>A p.E1572K | Missense Mutation (SNP) | VAF 74/171 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs747884990, COSV57488372; called by muse, mutect2, varscan2
- DOCK1 | c.4114G>T p.A1372S | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.88); PolyPhen benign (0.028); catalogued as rs756633592; called by muse, mutect2, varscan2
- DST | c.4896G>T p.E1632D | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs753295452, COSV54997759, COSV99754072; called by muse, mutect2, varscan2
- FERMT2 | c.1192A>C p.T398P | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV58407844; called by muse, mutect2, varscan2
- GIMAP8 | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 72/234 reads (31%) | catalogued as rs746795576; called by mutect2, varscan2
- GPC3 | c.1018A>T p.K340* | Nonsense Mutation (SNP) | VAF 27/72 reads (38%) | catalogued as CM001187; called by muse, mutect2, varscan2
- GPR6 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0.02); catalogued as rs1004146420, COSV51573272; called by muse, mutect2, varscan2
- GTF3C1 | c.5232G>T p.E1744D | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.314); catalogued as COSV100649452; called by muse, mutect2, varscan2
- IGHV1-69D | c.262A>G p.T88A | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs1191065504; called by muse, varscan2
- IGHV2-70 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs185317654; called by muse, varscan2
- IGHV2-70 | c.107C>G p.T36S | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.332); catalogued as rs548028630; called by muse, varscan2
- IGHV2-70 | c.68T>C p.L23S | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs189702615; called by muse, varscan2
- IL6ST | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61139708; called by muse, varscan2
- KCNK15 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs771995219; called by muse, mutect2, varscan2
- KPTN | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs766191198; called by muse, mutect2, varscan2
- LAMA2 | c.2927C>A p.S976* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV70346457; called by muse, mutect2, varscan2
- NALCN | c.3511G>A p.D1171N | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV51952860, COSV99213576; called by muse, mutect2, varscan2
- OR1L3 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 81/271 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs372271162, COSV59170851; called by muse, mutect2, varscan2
- PCSK5 | c.1384G>T p.V462F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65083718, COSV65089270; called by muse, mutect2, varscan2
- PRX | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs368874138; called by muse, mutect2, varscan2
- RPGRIP1 | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.96); catalogued as rs1218981990; called by muse, mutect2, varscan2
- RYR1 | c.3804C>A p.C1268* | Nonsense Mutation (SNP) | VAF 23/82 reads (28%) | catalogued as COSV100614086; called by muse, mutect2, varscan2
- SCN9A | c.3196G>A p.V1066M (on ENST00000303354; = p.V1055M on NM_002977.3) | Missense Mutation (SNP) | VAF 88/182 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as rs1384581509; called by muse, mutect2, varscan2
- SPANXD | c.234C>G p.N78K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs781909487, COSV100982271, COSV65152551; called by muse, mutect2, varscan2
- SPTBN5 | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1238021477, COSV58016159; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 41/99 reads (41%) | PolyPhen benign (0.317); catalogued as rs761701084; called by muse, mutect2, varscan2
- TIMM29 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs757173956, COSV53403631; called by muse, mutect2, varscan2
- TNFRSF1B | c.1007G>A p.S336N | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV66164212; called by muse, mutect2, varscan2
- UGT1A10 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs149598882; called by muse, mutect2, varscan2
- WWC3 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1418681309, COSV66504998; called by muse, varscan2
- ZMYND8 | c.1745C>T p.T582M (on ENST00000311275 / NM_001363741.2; = p.T602M on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); catalogued as rs773983281, COSV53682171; called by muse, mutect2, varscan2
- ZNF467 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.846); catalogued as rs750542028; called by muse, mutect2
- ZNF502 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 83/248 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1356701357; called by muse, mutect2, varscan2
- ACE | c.212A>G p.H71R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- ADGRD2 | c.2388G>T p.W796C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ADGRL3 | c.2133C>G p.N711K (on ENST00000506720 / NM_001322402.2; = p.N643K on NM_015236.6) | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- APEH | c.1703A>G p.E568G | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ATP6V1A | c.1794A>T p.K598N | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- ATRX | c.6181A>T p.K2061* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- BAG6 | c.998C>A p.A333E | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BMP2K | c.2494C>A p.L832I | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1E | c.6341C>A p.P2114Q (on ENST00000367573 / NM_001205293.3; = p.P2071Q on NM_000721.4) | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- CCDC168 | c.17293G>T p.E5765* | Nonsense Mutation (SNP) | VAF 57/70 reads (81%) | called by muse, mutect2, varscan2
- CCDC168 | c.8177dup p.S2727Lfs*2 | Frame Shift Ins (INS) | VAF 34/38 reads (89%) | called by mutect2, varscan2
- CEP290 | c.5600C>T p.T1867I | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD3 | c.1502C>T p.T501I | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT tolerated (0.05); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- CMYA5 | c.6386C>A p.P2129H | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- COL6A1 | c.159G>T p.K53N | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CSMD3 | c.6942A>T p.R2314S (on ENST00000297405 / NM_001363185.1; = p.R2210S on NM_052900.3) | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- CWF19L2 | c.1681A>G p.N561D | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DNAH3 | c.2118C>A p.S706R | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DOCK8 | c.316T>G p.S106A | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EYS | c.3388A>G p.I1130V | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GALNT15 | c.1048A>G p.K350E | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); called by muse, mutect2
- GFAP | c.1415T>G p.M472R (on ENST00000253408 / NM_001363846.2; = p.M432R on NM_002055.5) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- GGT5 | c.1242G>T p.M414I | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- GSDMC | c.451A>G p.R151G | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HBS1L | c.723del p.R242Gfs*4 | Frame Shift Del (DEL) | VAF 60/191 reads (31%) | called by mutect2, pindel, varscan2
- HMCN2 | c.5598G>C p.R1866S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- HRC | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- JCAD | c.1501T>C p.W501R | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.012); called by muse, mutect2
- KIAA1549L | c.2544C>A p.F848L (on ENST00000321505; = p.F1145L on NM_012194.3) | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1958 | c.554G>T p.S185I | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- LAMA1 | c.7245G>T p.K2415N | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MAGEF1 | c.473A>G p.E158G | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by mutect2, varscan2
- MGAM2 | c.4766G>A p.R1589Q | Missense Mutation (SNP) | VAF 113/173 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MON2 | c.3064T>C p.W1022R | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MROH2A | c.2448+1G>A p.X816_splice | Splice Site (SNP) | VAF 44/89 reads (49%) | called by muse, mutect2, varscan2
- MTOR | c.3288A>T p.L1096F | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- MXRA5 | c.6080C>A p.A2027D | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYNN | c.1538A>T p.N513I | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- NAT9 | c.489+2T>C p.X163_splice | Splice Site (SNP) | VAF 63/119 reads (53%) | called by muse, mutect2, varscan2
- NFKB2 | c.2390G>C p.R797P | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NKAPD1 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 24/460 reads (5%) | called by muse, mutect2
- NOS1AP | c.24C>G p.N8K | Missense Mutation (SNP) | VAF 77/277 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NOX4 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- NSD2 | c.1923C>A p.Y641* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- NUP214 | c.3779G>C p.G1260A | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- OR2M4 | c.691G>T p.G231W | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OR5AK2 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRRT3 | c.1738G>A p.V580M | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- RAX | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.52); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- RCC1 | c.1107G>A p.W369* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- RIMS1 | c.1508C>T p.S503L | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- SLC44A4 | c.124C>A p.L42M | Missense Mutation (SNP) | VAF 71/233 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SPTBN5 | c.10833A>T p.L3611F | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- SSPOP | n.6099+2T>A | Splice Site (SNP) | VAF 47/167 reads (28%) | called by muse, mutect2, varscan2
- TRAV40 | c.19T>G p.F7V | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTN | c.22301C>T p.T7434I (on ENST00000591111; = p.T6507I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/113 reads (46%) | PolyPhen benign (0.294); called by muse, mutect2, varscan2
- VCP | c.901_903del p.I301del | In Frame Del (DEL) | VAF 80/268 reads (30%) | called by pindel, varscan2
- ZC3HAV1L | c.173A>G p.E58G | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.201); called by muse, mutect2
- ZIC3 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ACE2 | c.282G>A p.K94= | Silent (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- ANKRD30B | c.3621A>G p.G1207= | Silent (SNP) | VAF 186/275 reads (68%) | called by muse, mutect2, varscan2
- ANKRD53 | c.564C>A p.T188= | Silent (SNP) | VAF 50/107 reads (47%) | called by muse, mutect2, varscan2
- ATP2A3 | c.1449C>T p.F483= | Silent (SNP) | VAF 45/48 reads (94%) | called by muse, mutect2, varscan2
- C11orf97 | c.363C>T p.H121= | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as rs377262767; called by muse, mutect2, varscan2
- CYP39A1 | c.1266A>G p.L422= | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- DHX32 | c.882A>G p.Q294= | Silent (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- ENTPD7 | c.720T>G p.A240= | Silent (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- EVI5L | c.423C>T p.S141= | Silent (SNP) | VAF 75/259 reads (29%) | catalogued as rs375245918; called by muse, mutect2, varscan2
- EXTL1 | c.1578G>A p.T526= | Silent (SNP) | VAF 45/86 reads (52%) | catalogued as rs375085844; called by muse, mutect2, varscan2
- GRHL2 | c.507C>T p.A169= | Silent (SNP) | VAF 105/113 reads (93%) | called by muse, mutect2, varscan2
- HAUS8 | c.1029C>A p.P343= | Silent (SNP) | VAF 49/146 reads (34%) | called by muse, mutect2, varscan2
- HPX | c.324C>G p.V108= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- IGLV3-1 | c.214C>A p.R72= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as rs61731683; called by muse, varscan2
- KRT2 | c.1071G>A p.E357= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs1448152242; called by muse, mutect2, varscan2
- KRT3 | c.1020C>T p.D340= | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as rs150031039; called by muse, mutect2, varscan2
- MEGF8 | c.2781C>T p.D927= (on ENST00000251268 / NM_001271938.2; = p.D860= on NM_001410.3) | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as rs761765707, COSV99234659; called by muse, mutect2, varscan2
- MMP11 | c.913C>A p.R305= | Silent (SNP) | VAF 49/113 reads (43%) | catalogued as rs1267449886, COSV99303480; called by muse, mutect2, varscan2
- NPHP1 | c.1002G>A p.T334= (on ENST00000393272 / NM_207181.4; = p.T335= on NM_000272.5) | Silent (SNP) | VAF 38/74 reads (51%) | called by muse, mutect2, varscan2
- NRXN2 | c.1516C>T p.L506= | Silent (SNP) | VAF 42/150 reads (28%) | catalogued as rs371149295; called by muse, mutect2, varscan2
- RABL6 | c.1563A>C p.P521= | Silent (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- SLC4A7 | c.2499C>T p.F833= | Silent (SNP) | VAF 51/165 reads (31%) | called by muse, mutect2, varscan2
- TCHH | c.4851C>T p.R1617= | Silent (SNP) | VAF 86/252 reads (34%) | catalogued as rs546393522, COSV100915671; called by muse, mutect2, varscan2
- TOR2A | c.765C>T p.D255= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs758069979, COSV60161575; called by muse, mutect2, varscan2
- AC020637.1 | n.976A>G | RNA (SNP) | VAF 111/276 reads (40%) | called by muse, mutect2, varscan2
- ACTRT1 | c.-35T>G | 5'UTR (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3625+400A>T | Intron (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- ADNP2 | c.*103T>G | 3'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.1599+77C>T | Intron (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2
- ATXN1 | c.*4877G>A | 3'UTR (SNP) | VAF 23/97 reads (24%) | called by muse, mutect2, varscan2
- BX842568.2 | n.512G>T | RNA (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- CACNG6 | c.*104C>A | 3'UTR (SNP) | VAF 114/450 reads (25%) | called by muse, mutect2, varscan2
- CCDC8 | c.*820A>G | 3'UTR (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- CDIPT | chr16:29863399 A>C | 5'Flank (SNP) | VAF 25/54 reads (46%) | called by muse, mutect2, varscan2
- CFL2 | c.*682G>T | 3'UTR (SNP) | VAF 51/114 reads (45%) | catalogued as rs1047772179; called by muse, mutect2, varscan2
- CLASP2 | c.715+4402T>G | Intron (SNP) | VAF 81/255 reads (32%) | called by muse, mutect2, varscan2
- COG7 | c.*314A>T | 3'UTR (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- CRELD1 | c.460+11A>C | Intron (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- CSF1R | c.-133C>G | 5'UTR (SNP) | VAF 61/122 reads (50%) | called by muse, mutect2, varscan2
- DCUN1D1 | c.*4623G>T | 3'UTR (SNP) | VAF 29/89 reads (33%) | called by muse, mutect2, varscan2
- DNAJC2 | c.331+1048G>A | Intron (SNP) | VAF 43/57 reads (75%) | catalogued as rs1041201085; called by muse, mutect2, varscan2
- DNM1 | c.1335+1668C>A | Intron (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- DUS4L-BCAP29 | c.*1054A>G | 3'UTR (SNP) | VAF 67/125 reads (54%) | catalogued as rs1176718355; called by muse, mutect2, varscan2
- ELAVL2 | c.*298A>G | 3'UTR (SNP) | VAF 48/143 reads (34%) | called by muse, mutect2, varscan2
- EXTL1 | c.-602C>A | 5'UTR (SNP) | VAF 42/85 reads (49%) | called by muse, mutect2, varscan2
- FBLN7 | c.532+123C>A | Intron (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- FST | c.*508C>G | 3'UTR (SNP) | VAF 37/79 reads (47%) | called by muse, mutect2, varscan2
- GLDC | c.*130C>T | 3'UTR (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- GRIK4 | c.907-4595G>C | Intron (SNP) | VAF 32/103 reads (31%) | called by muse, mutect2, varscan2
- GTF2E1 | c.*1555T>C | 3'UTR (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- GUSB | c.-8C>G | 5'UTR (SNP) | VAF 32/65 reads (49%) | called by muse, mutect2, varscan2
- HBZ | c.-257C>A | 5'UTR (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- HNRNPA2B1 | c.-144C>T | 5'UTR (SNP) | VAF 24/76 reads (32%) | catalogued as rs760113718; called by muse, mutect2, varscan2
- HNRNPCL1 | c.-172T>G | 5'UTR (SNP) | VAF 56/230 reads (24%) | called by muse, mutect2, varscan2
- HOMER2 | c.*650G>A | 3'UTR (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- HSPA4L | c.*664A>G | 3'UTR (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- HSPH1 | chr13:31162009 C>G | 5'Flank (SNP) | VAF 30/133 reads (23%) | called by muse, mutect2, varscan2
- IGHV3-23 | c.-15C>T | 5'UTR (SNP) | VAF 15/75 reads (20%) | catalogued as rs782077115; called by muse, mutect2
- INO80D | c.*927C>T | 3'UTR (SNP) | VAF 49/100 reads (49%) | called by muse, mutect2, varscan2
- JMJD8 | c.*895G>C | 3'UTR (SNP) | VAF 63/117 reads (54%) | called by muse, mutect2, varscan2
- KCTD20 | c.*1090A>G | 3'UTR (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- KLK11 | c.*81C>A | 3'UTR (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- LCN2 | c.*7+74C>G | Intron (SNP) | VAF 38/109 reads (35%) | called by muse, mutect2, varscan2
- LDLRAD2 | c.*2246C>A | 3'UTR (SNP) | VAF 28/50 reads (56%) | called by muse, mutect2, varscan2
- LHPP | c.*555C>T | 3'UTR (SNP) | VAF 41/85 reads (48%) | called by muse, mutect2, varscan2
- LINC02035 | n.409G>T | RNA (SNP) | VAF 27/102 reads (26%) | called by muse, mutect2, varscan2
- LPAR4 | c.-55A>C | 5'UTR (SNP) | VAF 72/138 reads (52%) | called by muse, mutect2, varscan2
- LPGAT1 | chr1:211749561 A>G | 3'Flank (SNP) | VAF 67/105 reads (64%) | called by muse, mutect2, varscan2
- LRP8 | c.367+100A>T | Intron (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2
- LRRC18 | c.-51T>C | 5'UTR (SNP) | VAF 61/125 reads (49%) | catalogued as rs1286121703; called by muse, mutect2, varscan2
- LRRTM4 | c.1551+324C>A | Intron (SNP) | VAF 50/104 reads (48%) | called by muse, mutect2, varscan2
- LTB | c.163-54A>G | Intron (SNP) | VAF 210/376 reads (56%) | called by muse, varscan2
- LTB | c.163-159A>G | Intron (SNP) | VAF 104/195 reads (53%) | called by muse, varscan2
- MAPK3 | c.171-459G>A | Intron (SNP) | VAF 65/106 reads (61%) | called by muse, mutect2, varscan2
- MDGA1 | c.*4395G>A | 3'UTR (SNP) | VAF 38/61 reads (62%) | catalogued as rs774246362, COSV99776766; called by muse, mutect2, varscan2
- MGAT4D | chr4:140498350 G>A | 5'Flank (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- MICAL3 | c.2801+367G>T | Intron (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851275 T>C | 5'Flank (SNP) | VAF 60/146 reads (41%) | catalogued as rs542998783; called by muse, mutect2, varscan2
- MKLN1 | c.*6381G>T | 3'UTR (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- MNX1 | c.691+425G>C | Intron (SNP) | VAF 67/216 reads (31%) | called by muse, mutect2, varscan2
- MON2 | c.*2374T>C | 3'UTR (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- MRS2 | c.1221+142G>C | Intron (SNP) | VAF 55/205 reads (27%) | called by muse, mutect2, varscan2
- MTIF3 | c.-1-15T>C | Intron (SNP) | VAF 65/158 reads (41%) | catalogued as rs1447983340; called by muse, mutect2, varscan2
- MYO10 | c.279+3071T>C | Intron (SNP) | VAF 91/127 reads (72%) | called by muse, mutect2, varscan2
- NACA | c.70+3775G>C | Intron (SNP) | VAF 56/98 reads (57%) | catalogued as COSV100771718; called by muse, mutect2, varscan2
- NANOS1 | c.*955A>G | 3'UTR (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- NFIA | c.*3850C>A | 3'UTR (SNP) | VAF 37/62 reads (60%) | called by muse, mutect2, varscan2
- NHS | c.*3101C>T | 3'UTR (SNP) | VAF 34/60 reads (57%) | called by muse, mutect2, varscan2
- NPTN | c.-132C>G | 5'UTR (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- NR3C2 | c.*1539G>T | 3'UTR (SNP) | VAF 58/147 reads (39%) | called by muse, mutect2, varscan2
- NRDE2 | c.*988T>G | 3'UTR (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- NTNG1 | c.1087+2265C>T | Intron (SNP) | VAF 21/52 reads (40%) | catalogued as rs1000042553, COSV53965372; called by muse, mutect2, varscan2
- OGFR | c.172-411C>G | Intron (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- OR1G1 | c.*26G>T | 3'UTR (SNP) | VAF 49/57 reads (86%) | catalogued as rs1194501988; called by muse, mutect2, varscan2
- OR2F1 | c.*39T>A | 3'UTR (SNP) | VAF 92/287 reads (32%) | called by muse, mutect2, varscan2
- PCDH17 | c.*1053C>T | 3'UTR (SNP) | VAF 33/38 reads (87%) | called by muse, mutect2, varscan2
- PDE7B | c.*1899C>A | 3'UTR (SNP) | VAF 38/104 reads (37%) | called by muse, mutect2, varscan2
- PEAR1 | c.903-27G>A | Intron (SNP) | VAF 92/139 reads (66%) | catalogued as rs769187229; called by muse, mutect2, varscan2
- POLR2H | c.*261dup | 3'UTR (INS) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- PPP2R3B | c.*308G>T | 3'UTR (SNP) | VAF 7/11 reads (64%) | catalogued as rs770671539; called by muse, mutect2, varscan2
- PRRT1 | c.*638G>A | 3'UTR (SNP) | VAF 54/183 reads (30%) | called by muse, mutect2, varscan2
- PSMG4 | c.250+1369C>T | Intron (SNP) | VAF 25/82 reads (30%) | catalogued as rs1446357743; called by muse, mutect2, varscan2
- PTPRD | c.*150A>T | 3'UTR (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- RAB27B | c.*5848A>G | 3'UTR (SNP) | VAF 37/99 reads (37%) | called by muse, mutect2, varscan2
- RAD51 | c.*344T>C | 3'UTR (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- RAN | chr12:130877045 T>G | 3'Flank (SNP) | VAF 20/44 reads (45%) | called by muse, varscan2
- RGS7BP | c.*1349C>A | 3'UTR (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- RGS8 | chr1:182646412 A>T | 3'Flank (SNP) | VAF 26/93 reads (28%) | called by muse, mutect2, varscan2
- SKA1 | c.*1540G>C | 3'UTR (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- SLC12A1 | c.628+1525A>G | Intron (SNP) | VAF 39/106 reads (37%) | called by muse, mutect2, varscan2
- SLC23A2 | c.*4347A>C | 3'UTR (SNP) | VAF 43/92 reads (47%) | called by muse, mutect2, varscan2
- SLCO2B1 | c.1829-72G>A | Intron (SNP) | VAF 46/114 reads (40%) | called by muse, mutect2, varscan2
- SOX6 | chr11:15969804 T>C | 3'Flank (SNP) | VAF 74/122 reads (61%) | called by muse, mutect2, varscan2
- SRRM4 | c.*235A>G | 3'UTR (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- SRRM4 | c.*2129C>A | 3'UTR (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- ST6GALNAC3 | c.*1529C>T | 3'UTR (SNP) | VAF 10/104 reads (10%) | catalogued as rs187195490; called by muse, mutect2, varscan2
- SULF1 | c.2285-25T>C | Intron (SNP) | VAF 50/52 reads (96%) | called by muse, mutect2, varscan2
- SVIL | chr10:29457897 A>G | 3'Flank (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- TBC1D9B | c.2966-34G>T | Intron (SNP) | VAF 14/22 reads (64%) | called by muse, varscan2
- TIAM1 | c.*618G>C | 3'UTR (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- TIFA | c.*422dup | 3'UTR (INS) | VAF 25/52 reads (48%) | called by mutect2, pindel, varscan2
- TOX4 | c.*1213A>G | 3'UTR (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- TP53 | c.993+282T>C | Intron (SNP) | VAF 78/92 reads (85%) | called by muse, mutect2, varscan2
- TP63 | c.1350-5224G>T | Intron (SNP) | VAF 48/132 reads (36%) | called by muse, mutect2, varscan2
- TRAPPC2L | c.375-108C>A | Intron (SNP) | VAF 20/22 reads (91%) | called by muse, mutect2
- TWSG1 | c.*2884dup | 3'UTR (INS) | VAF 18/58 reads (31%) | called by mutect2, pindel, varscan2
- VMA21 | chrX:151396873 G>C | 5'Flank (SNP) | VAF 74/152 reads (49%) | called by muse, mutect2
- VNN1 | c.*246A>T | 3'UTR (SNP) | VAF 25/103 reads (24%) | called by muse, mutect2, varscan2
- VPS36 | c.774+29T>A | Intron (SNP) | VAF 22/26 reads (85%) | catalogued as rs200170312; called by muse, varscan2
- VTA1 | c.*2237dup | 3'UTR (INS) | VAF 23/68 reads (34%) | catalogued as rs1411257765; called by mutect2, varscan2
- WNT11 | c.*17C>A | 3'UTR (SNP) | VAF 62/200 reads (31%) | called by muse, mutect2, varscan2
- ZDHHC14 | c.*2768A>T | 3'UTR (SNP) | VAF 45/91 reads (49%) | called by muse, mutect2, varscan2
- ZNF747 | c.*2433_*2436del | 3'UTR (DEL) | VAF 9/73 reads (12%) | catalogued as rs140677615; called by mutect2, pindel, varscan2
- ZNF780A | c.*115T>A | 3'UTR (SNP) | VAF 31/132 reads (23%) | catalogued as rs1221424571; called by muse, mutect2, varscan2
